Somatic mutation profile of tumor specimen ALCH-AE71-TTP1-A (aliquot ALCH-AE71-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE71, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.0 years (21,926 days).
Specimen ALCH-AE71-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f3fd9a5-28a1-44b1-9421-53429010c2bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE71-NB1-A (Blood Derived Normal), aliquot ALCH-AE71-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08250354-e181-45df-88a4-246142671f25

The open-access MAF lists 71 somatic variants for this specimen: 45 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 21, Nonsense Mutation 3, Intron 2, 3'Flank 2, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPRIN2 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 39/974 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.011); catalogued as COSV99195771; called by muse, mutect2
- CDKN2A | c.150+1G>C p.X50_splice | Splice Site (SNP) | VAF 15/440 reads (3%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2
- CPN1 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 38/865 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs754989179; called by muse, mutect2
- CTNNA2 | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 12/368 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58183951; called by muse, mutect2
- EHD2 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.017); catalogued as rs796785999, COSV54408668; called by muse, mutect2
- FAM135B | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99428488; called by muse, mutect2
- FAM47C | c.2245A>T p.S749C | Missense Mutation (SNP) | VAF 35/504 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV63731849; called by muse, mutect2
- FPR2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 15/443 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60672165; called by muse, mutect2
- LILRB3 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT tolerated (0.54); catalogued as rs1305789825; called by muse, mutect2
- LRRTM1 | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99702258; called by muse, mutect2
- MSGN1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99808771; called by muse, mutect2
- PDE3A | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 40/934 reads (4%) | catalogued as rs1394499677, COSV100761695; called by muse, mutect2
- PTPRD | c.3190G>A p.D1064N | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1338134782, COSV100647481; called by muse, mutect2
- RAPGEF4 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV51418432; called by muse, mutect2
- ADCY3 | c.2713C>G p.L905V | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- ARX | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 23/399 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CAMSAP1 | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.107); called by muse, mutect2
- CCL14 | c.158A>C p.Y53S (on ENST00000618404 / NM_032963.4; = p.Y69S on NM_032962.4) | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CEP85L | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- CHAT | c.163C>G p.P55A | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- DRC1 | c.1571A>G p.Y524C | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- FANCL | c.816T>A p.H272Q | Missense Mutation (SNP) | VAF 56/970 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); called by muse, mutect2
- FPR3 | c.438G>C p.M146I | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FSHR | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.159); called by muse, mutect2
- GFI1B | c.941A>T p.Q314L | Missense Mutation (SNP) | VAF 33/427 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GRIN2B | c.2361G>A p.G787= | Splice Region (SNP) | VAF 22/576 reads (4%) | called by muse, mutect2
- IL1RAP | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | called by muse, varscan2
- LRRC7 | c.1016T>G p.L339* (on ENST00000651989 / NM_001370785.2; = p.L306* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/468 reads (3%) | called by muse, mutect2
- MAGEB16 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- MAPT | c.1118C>A p.P373H (on ENST00000262410 / NM_001377265.1; = p.P298H on NM_016835.4) | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2
- MORC1 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 13/453 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2
- PANK3 | c.201C>A p.H67Q | Missense Mutation (SNP) | VAF 29/728 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- PAX1 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 29/1128 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PIGR | c.1207G>T p.G403W | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POU6F2 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 18/672 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- PPP4R3C | c.122T>A p.L41H | Missense Mutation (SNP) | VAF 22/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRRC2A | c.3606G>T p.L1202F | Missense Mutation (SNP) | VAF 17/392 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2
- RGS22 | c.906T>A p.D302E | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- SAMHD1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 32/754 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDK1 | c.3862G>T p.V1288F | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SNUPN | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 17/503 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2
- SORCS1 | c.1117G>C p.V373L | Missense Mutation (SNP) | VAF 20/649 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2
- SYTL5 | c.1456C>A p.L486M | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBC1D30 | c.968G>T p.R323L (on ENST00000542120; = p.R160L on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZIC4 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 57/991 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ADRB3 | c.180G>A p.V60= | Silent (SNP) | VAF 29/588 reads (5%) | called by muse, mutect2
- C1S | c.1470C>T p.T490= | Silent (SNP) | VAF 24/824 reads (3%) | catalogued as rs1455806277; called by muse, mutect2
- CACNA1H | c.883C>A p.R295= | Silent (SNP) | VAF 13/246 reads (5%) | called by muse, mutect2
- CHST2 | c.1083G>A p.P361= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1437216641; called by muse, mutect2, varscan2
- CTNNA2 | c.2142G>T p.L714= | Silent (SNP) | VAF 12/357 reads (3%) | called by muse, mutect2
- CTNND2 | c.2742T>C p.T914= | Silent (SNP) | VAF 16/448 reads (4%) | called by muse, mutect2
- DNAH2 | c.9669C>T p.A3223= | Silent (SNP) | VAF 16/444 reads (4%) | called by muse, mutect2
- EPB41L3 | c.2385C>T p.G795= | Silent (SNP) | VAF 19/635 reads (3%) | called by muse, mutect2
- FAT3 | c.7458A>G p.V2486= | Silent (SNP) | VAF 10/350 reads (3%) | called by muse, mutect2
- GRIK2 | c.1722C>A p.V574= | Silent (SNP) | VAF 15/387 reads (4%) | called by muse, mutect2
- MAGEA1 | c.474C>T p.D158= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as rs782245100, COSV63119140; called by muse, mutect2
- MAGEB1 | c.282C>A p.S94= | Silent (SNP) | VAF 24/293 reads (8%) | catalogued as COSV66775644; called by muse, mutect2
- MARCHF8 | c.282C>A p.I94= | Silent (SNP) | VAF 11/230 reads (5%) | catalogued as COSV60575375; called by muse, mutect2
- MSANTD3 | c.519A>T p.S173= | Silent (SNP) | VAF 14/373 reads (4%) | called by muse, mutect2
- NXNL2 | c.219C>T p.D73= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as rs1331267528; called by muse, mutect2
- PLEKHG4 | c.2790G>A p.Q930= | Silent (SNP) | VAF 22/462 reads (5%) | catalogued as COSV100430752; called by muse, mutect2
- RYR2 | c.12435C>T p.I4145= | Silent (SNP) | VAF 14/322 reads (4%) | catalogued as rs954641240, COSV63671059, COSV63678927; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1890A>G p.A630= (on ENST00000540229 / NM_001371097.1; = p.A569= on NM_001009562.4) | Silent (SNP) | VAF 9/276 reads (3%) | catalogued as rs1448894758; called by muse, mutect2
- WARS2 | c.765G>T p.V255= | Silent (SNP) | VAF 36/1142 reads (3%) | called by muse, mutect2
- ZFC3H1 | c.519A>G p.R173= | Silent (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- ZNF841 | c.1818A>T p.T606= (on ENST00000426391 / NM_001369830.1; = p.T722= on NM_001136499.1 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- AC016582.1 | chr19:37824589 G>T | 3'Flank (SNP) | VAF 22/644 reads (3%) | called by muse, mutect2
- AC100868.1 | c.152-2052T>C | Intron (SNP) | VAF 40/792 reads (5%) | catalogued as rs193023467; called by muse, mutect2
- MIR513B | n.69G>A | RNA (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- PMPCB | c.99+159G>A | Intron (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- PRCD | chr17:76544692 G>A | 3'Flank (SNP) | VAF 34/1007 reads (3%) | called by muse, mutect2
